Surgical pathology report (de-identified scan), TCGA case TCGA-57-1586, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-57-1586-01A (Primary Tumor).

PHYSICIAN INFORMATION

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A&C. Ovaries, right and left, salpingectomies:
Papillary serous adenocarcinoma.
Grade III.
Totally replaces both ovaries.
Lymphovascular space invasion present.
Involvement of cortical surface and attached soft tissue present.
- B. Omentum, omentectomy:
Metastatic papillary serous adenocarcinoma (extensive).

Staging: T3c, NX, M1 (FIGO: IV)

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Mass and ascities, CA125 = 1330 grams ovarian cancer
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right ovary
B. Omentum
C. Left ovary

SPECIMEN DATA

GROSS DESCRIPTION:

- A. The first container A is labeled with the patient's name [REDACTED]. The specimen consists of a yellow to gray tan hemorrhagic soft tissue mass measuring 6.0 x 5.0 x 3.0 cm. The cut surface is yellow gray fibrotic. Normal ovarian tissue is not grossly recognized. Representative sections were taken for genomic studies and placed in orange cassettes labeled A, C, and D. Also received with the specimen are two cassettes, one green and one yellow, labeled [REDACTED]. Representative sections are submitted in six cassettes labeled: [REDACTED] ✓
- B. The second container B is labeled with the patient's name [REDACTED]. The specimen consists of multiple pieces of yellow tan to gray tan fibroadipose omentum tissue measuring 25.0 x 11.0 x 3.0 cm. The cut surface displays gray tan fibrotic band tissue intermixed within the fibroadipose tissue. Representative sections are submitted in two cassettes [REDACTED]
- C. The third container C is labeled with the patient's name [REDACTED]. The specimen consists of a yellow gray slightly hemorrhagic soft issue mass measuring 4.5 x 3.5 x 3.0 cm. On sectioning the cut surface is yellow gray slightly hemorrhagic fleshy. Normal ovarian tissue is not grossly identified. Representative sections are submitted in five cassettes [REDACTED]

Source: NCI Genomic Data Commons file d4a981f6-1800-4a2d-b67e-9419674bdfe8 (TCGA-57-1586.1245D63D-8859-496A-828E-4CCAD717C114.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).